Surgical pathology report (de-identified scan), TCGA case TCGA-55-8302, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8302-01A (Primary Tumor).

[page 1 of 4]
Sex:M

MR#:

SURGICAL PATHOLOGY

SURGERY CASE #: [REDACTED] FINAL

DATE OF SURGERY: [REDACTED]

SURGEON: [REDACTED]

SPECIMEN: A. Right lower lobe, lung wedge.
B. Level 10 R
C. Level 4R
D. Level 11R A
E. Right lower lobe - bronchial
margins.

F. Level 11R B
G. Level 11R C
H. Level 11R D
I. Level 7

FROZEN SECTION DIAGNOSIS: A. Carcinoma. [REDACTED]
E. Bronchial surgical margins free of
tumor. [REDACTED]

OPERATIVE PROCEDURE: Right VATS
PREOPERATIVE DIAGNOSIS: Right lung mass.
POSTOPERATIVE DIAGNOSIS: Def

*****DIAGNOSIS*****

A-I.

1. Type of specimen:
Right lower lobe lobectomy with lymph node biopsies.
2. Tumor type:
Pulmonary adenocarcinoma.
3. Histologic grade:
Moderately to poorly differentiated.
4. Tumor size:
1.2 cm.
5. Surgical margins:
All surgical margins free of tumor.
6. Direct extension of tumor:
Tumor focally invades into, but not through, visceral pleura.
7. Lymphatic (small vessel) invasion:
Focus suggestive of lymphatic invasion identified.
8. Venous (large vessel) invasion:
Absent.
9. Lymph nodes:
Total number of lymph nodes examined: 7.
Number of lymph nodes involved: 0 (0/7).

[page 2 of 4]
10. TNM STAGING:
pT2, pN0, pMX

NOTE: Current NCCN practice guidelines recommend determination of EGFR and KRAS mutation status in adenocarcinoma of lung to help select patients for Tyrosine-Kinase Inhibitor (TKI) therapy. Additionally, recent data show that ALK (anaplastic lymphoma kinase) gene rearrangements in adenocarcinoma of lung are associated with resistance to TKIs. EGFR activating mutations have been shown to be significantly associated with response to TKI and KRAS mutations are associated with TKI resistance. Mutation analysis for KRAS and EGFR domain and ALK gene rearrangement by FISH is available as the lung cancer mutation panel upon request. Testing may be performed on paraffin-embedded tissue (block A3).

MICROSCOPIC EXAMINATION:

- A. Multiple sections are examined and sections of the mass grossly described demonstrates a malignant epithelial neoplasm. The tumor demonstrates nests and glandular differentiation of cells demonstrating a moderate to abundant amount of cytoplasm with enlarged, pleomorphic nuclei with irregular clumped chromatin pattern and prominent nucleoli. There is mitotic activity seen. The tumor is seen focally extending to, but not through, the visceral pleura which is also examined with elastic stain. Immunohistochemistry stains are also performed and the neoplastic cells are strongly positive with cytokeratin 7, positive with cytokeratin 20, positive with Napsin-A and show strong nuclear staining with TTF-1. There is no venous (large vessel) invasion. A focus highly suggestive of lymphatic invasion is noted. Sections of the grossly uninvolved lung demonstrate no significant fibrosis or significant inflammation.
- B. Sections demonstrate fragments of benign lymph node with mild anthracosis. There is no malignancy.
- C. Sections demonstrate fragments of benign lymph node with anthracotic pigment. There is no malignancy.
- D. Sections are of a benign lymph node with findings as described above. There is no malignancy.
- E. Multiple sections are examined and the bronchial margins are free of tumor. The vascular margins are also unremarkable. Sections from the previous wedge resection site demonstrate lung parenchyma with hemorrhage. There is no residual tumor. Random sections of the grossly unremarkable lung demonstrate no significant inflammation with a few mildly thickened alveolar septae but no significant interstitial fibrosis.
- F. Sections are of a benign lymph node with sinus histiocytosis and anthracotic pigment. There is no malignancy.
- G. Sections are of a benign lymph node with findings as described above. There is no malignancy.
- H. Sections are of a benign lymph node with findings as described above. There is no malignancy.

[page 3 of 4]
- I. Sections are of a benign lymph node with findings as described above. There is no malignancy. [REDACTED]

GROSS:

- A. Received fresh labeled with the patient's name, account number, and "right lower lobe, lung wedge" is a wedge biopsy of lung measuring 10 x 3.5 x 3 cm in maximum dimensions. The pleural surface is red-brown, anthracotic, and contains a retracted area. The pleural surface is inked in black. Sectioning reveals a mass measuring 1.2 cm maximally with a gray-tan, mottled cut surface. Representative sections of the mass are submitted for frozen section and following permanent sections in a single cassette with touch preparations also performed. A portion of the mass is submitted to Precision Therapeutics for chemosensitivity studies. A separate report will be issued. The remainder of the lung demonstrates a red-brown, soft and spongy parenchyma with no additional masses identified. Additional sections are submitted in blocks #2 through #4 for permanent. Blocks #2 and #3, additional sections of mass. Block #4 - Grossly uninvolved lung. RS-4 [REDACTED]
- B. Received in Formalin labeled with the patient's name, account number, and "Level 10 R" are two fragments of anthracotic lymph node measuring 0.2 cm each. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]
- C. Received in Formalin labeled with the patient's name, account number, and "Level 4R" is a single fragment of yellow-tan adipose tissue measuring 1 x 0.7 x 0.6 cm in maximum dimensions. A search is made for potential lymph nodes and two are found measuring 0.4 and 0.6 cm. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]
- D. Received in Formalin labeled with the patient's name, account number, and "Level 11R A" is a single fragment of anthracotic lymph node measuring 1.2 x 0.5 x 0.3 cm in maximum dimensions. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]
- E. Received labeled "right lower lobe" is a 13.5 x 13 x 6 cm in maximum dimensions thoracotomy specimen. The bronchial margin is submitted for frozen and frozen section diagnosis in block #1. There is a staple line consistent with the previous wedge resection site. The specimen is serially sectioned and demonstrates parenchymal hemorrhage at the previous resection site with no residual tumor grossly seen. The remainder of the lung is soft and spongy with no additional masses. Sections are submitted for permanent as follows: Cassette #2 - Vascular margins. #3 and #4 - Sections from previous wedge resection. #5 - Random sections of lung. [REDACTED]
- F. The specimen is received fresh in a single container, labeled with the patient's name and number, and marked as "Level 11R B" is a single fragment of anthracotic lymph node measuring 1.1 x 0.5 x 0.3 cm in maximum dimensions. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]
- G. Received in Formalin labeled with the patient's name, account number, and "Level 11R C" is a single fragment of anthracotic lymph node measuring 0.4 x 0.3 x 0.2 cm in maximum dimensions. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]
- [REDACTED]

[page 4 of 4]
- H. Received in Formalin labeled with the patient's name, account number, and "Level 11R D" is a single fragment of anthracotic lymph node measuring 0.4 x 0.3 x 0.2 cm in maximum dimensions. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]
- I. Received in Formalin labeled with the patient's name, account number, and "Level 7" is a single fragment of anthracotic lymph node measuring 1.2 x 0.6 x 0.3 cm in maximum dimensions. The specimen is totally submitted in a single cassette. TS-1 [REDACTED]

Electronically Signed by

[REDACTED]

[REDACTED] MD

cc: [REDACTED] MD
[REDACTED] MD
[REDACTED] MD

[REDACTED]

Source: NCI Genomic Data Commons file 0e0ab909-6af4-4645-91c6-bff69e7bd8b7 (TCGA-55-8302.AA106E5A-B9B9-4F54-B902-120E8A3EB689.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).